FM case AD11020 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/5fdbc661-f0d9-4b91-9700-623e211d1326

Male, 55.0 years: Adenoid cystic carcinoma (ICD-O-3 8200/3) of the major salivary gland; primary biopsied or resected from the major salivary gland. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
